Somatic mutation profile of tumor specimen BA2677D (aliquot aq-BA2677D) from BEATAML1.0 case 2186, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,579 days).
Specimen BA2677D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4ed2aae-0cd4-4d43-b6a4-58cdf658f292.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2099D (Solid Tissue Normal), aliquot aq-BA2099D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cee0b0d1-c2a2-446c-9d8c-9948ed5588df

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- C12orf71 | c.182G>T p.W61L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV70282864; called by muse, mutect2
- SLC4A1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs186542577; called by muse, mutect2, varscan2
- C1QL4 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYBG1 | c.6150C>A p.D2050E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.805); called by muse, mutect2
- PLEKHG3 | c.3436C>A p.Q1146K (on ENST00000394691; = p.Q1202K on NM_001308147.2) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2
- EIF4G3 | c.1578A>G p.E526= | Silent (SNP) | VAF 58/96 reads (60%) | called by muse, mutect2, varscan2
- HUNK | c.144G>A p.R48= | Silent (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- SLC9B1P1 | n.484A>G | RNA (SNP) | VAF 16/129 reads (12%) | catalogued as rs768476671; called by muse, mutect2, varscan2
